Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A2N7, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A2N7-01A (Primary Tumor).

ADDENDA:
Addendum

MOLECULAR ANATOMIC PATHOLOGY TESTING:

(Thyroid left lobe and isthmus, papillary thyroid carcinoma with predominant follicular growth 5.0 cm):

Mutations in *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13* and *RET/PTC1* and *RET/PTC3* rearrangements NOT identified.

NOTE:

Nucleic acids were extracted in the amount sufficient for testing.

(Thyroid right lobe, papillary thyroid carcinoma with predominant follicular growth 1.8 cm):

Mutations in *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13* and *RET/PTC1* and *RET/PTC3* rearrangements NOT identified.

NOTE:

Nucleic acids were extracted in the amount sufficient for testing.

FINAL DIAGNOSIS:

PART 1: THYROID GLAND, LEFT AND ISTHMUS, LOBECTOMY AND ISTHMOSECTOMY (19 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, WITH PREDOMINANT FOLLICULAR GROWTH, 5.0 CM.
- B. EXTENSIVE VASCULAR INVASION IS IDENTIFIED.
- C. EXTRATHYROIDAL EXTENSION IS ABSENT.
- D. CARCINOMA IS <0.1 CM FROM THE MARGIN.
- E. PATHOLOGIC STAGE: pT3.

PART 2: THYROID GLAND, RIGHT, LOBECTOMY (7 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, WITH PREDOMINANT FOLLICULAR GROWTH, 1.8 CM.
- B. MULTIPLE FOCI OF CAPSULAR AND VASCULAR INVASION ARE IDENTIFIED.
- C. EXTRATHYROIDAL EXTENSION IS ABSENT.
- D. CARCINOMA IS <0.1 CM FROM THE MARGIN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Right Lobe, Left Lobe
TUMOR FOCALITY:	Multifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 5.0 cm
HISTOLOGIC TYPE**:	Papillary carcinoma
PRIMARY TUMOR (pT):	pT3
REGIONAL LYMPH NODES (pN):	pNX
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Not identified
MARGINS:	Margins uninvolved by carcinoma Distance of invasive carcinoma to closest margin: 1 mm
LYMPH-VASCULAR INVASION:	Present

ICD-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 w 8/18/11

Source: NCI Genomic Data Commons file 38d69392-2011-4bb1-bf05-f141ed77746f (TCGA-BJ-A2N7.F11C36D8-A39E-4CF2-8914-35B5164070F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).